Gene-level copy-number profile of tumor specimen HTMCP-03-06-02328-01A from CGCI case HTMCP-03-06-02328, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 58.2 years (21,271 days).
Specimen HTMCP-03-06-02328-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fc4260ab-cc03-4147-98fa-1a0b4f8febe3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02328-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/8085b5d0-d3b9-450c-9a28-1b9bf0e1ef20

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 8; copy number 2: 868; copy number 3: 6,847; copy number 4: 23,616; copy number 5: 10,696; copy number 6: 7,417; copy number 7: 7,765; copy number 8: 394; copy number 9: 175; copy number 10: 112; copy number 11: 40; copy number 13: 43; copy number 14: 86; copy number 15: 282; copy number 16: 36.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 774 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–33,298,066, 485 genes, copy number 9–15 (broad region; genes not listed).
- chr5:33,936,386–45,895,970, 188 genes, copy number 10–16 (broad region; genes not listed).
- chr7:38,239,580–38,249,572, 1 gene, copy number 14: TRGC2.
- chr7:38,256,337–38,350,022, 17 genes, copy number 10–15 (within-gene range 6–25): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRGV5P, TRGV5.
- chr7:142,618,849–142,793,368, 28 genes, copy number 11: TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr7:142,801,041–142,802,748, 1 gene, copy number 11: TRBC2.
- chr14:22,147,995–22,501,663, 53 genes, copy number 11–13: TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39.
- chr14:22,547,506–22,552,156, 1 gene, copy number 13: TRAC.

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
